Somatic mutation profile of tumor specimen MP2PRT-PATGGX-TMP1-A (aliquot MP2PRT-PATGGX-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATGGX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.1 years (1,501 days).
Specimen MP2PRT-PATGGX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f260aa1-8530-4bb9-80ef-0f363ecd8ff3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGGX-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGGX-NM1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b241223-ac5a-4616-b63b-ca2c59353884

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 53/236 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 31/241 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 159/346 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs113178652; called by muse, mutect2, varscan2
- CFTR | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs143860237, CM010793; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- MYH1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 57/869 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779598062, COSV56846716; called by muse, mutect2
- NRXN1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777800586; called by muse, mutect2
- PDE11A | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.324); catalogued as COSV53704601, COSV99613176; called by muse, varscan2
- SPTB | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 103/352 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767566180, COSV101072325, COSV67630315; called by muse, mutect2, varscan2
- DST | c.18118A>T p.R6040W (on ENST00000361203 / NM_001374722.1; = p.R3737W on NM_015548.5) | Missense Mutation (SNP) | VAF 64/410 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHV3-30 | chr14:106335072 TCACTGTGTCTTTCGCACAGTAATACAC>CCTTCAA | Missense Mutation (DEL) | VAF 71/427 reads (17%) | called by pindel, varscan2*
- IGHV4-31 | chr14:106349274 CTCATTGTGTCTCTGGCACAGTAA>TCTGTGGTAGG | Missense Mutation (DEL) | VAF 109/324 reads (34%) | called by pindel, varscan2*
- IGHV4-34 | c.368_369insTTCTACTCGG p.R123Sfs*? | Frame Shift Ins (INS) | VAF 102/299 reads (34%) | called by mutect2, pindel, varscan2
- KBTBD13 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 182/778 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SBK3 | c.526T>C p.C176R | Missense Mutation (SNP) | VAF 349/808 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- SLC4A10 | c.1965G>C p.M655I (on ENST00000446997 / NM_001354461.2; = p.M625I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZBTB44 | c.1228C>A p.R410S | Missense Mutation (SNP) | VAF 137/301 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- ADAM28 | c.2238C>A p.A746= | Silent (SNP) | VAF 26/216 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.85740C>A p.T28580= (on ENST00000591111; = p.T21156= on NM_003319.4) | Silent (SNP) | VAF 72/271 reads (27%) | catalogued as COSV99045401; called by muse, mutect2, varscan2
- ZNF503 | c.1467C>T p.G489= | Silent (SNP) | VAF 70/1144 reads (6%) | called by muse, mutect2
- IGHV2-5 | chr14:106037901 ins CA | 3'Flank (INS) | VAF 79/202 reads (39%) | called by mutect2, pindel, varscan2
